Surgical pathology report (de-identified scan), TCGA case TCGA-XD-AAUI, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Providence Portland Medical Center, specimen TCGA-XD-AAUI-01A (Primary Tumor).

[page 1 of 6]
Collected time and date

Clinical Information

Cancer pancreas head

Diagnosis

A. PERITONEAL NODULE

- Loculated degenerated bile with fibroinflammatory reaction.
- No evidence of malignancy.

B. RIGHT LIVER NODULE

- Loculated degenerated bile with fibroinflammatory reaction.
- No evidence of malignancy.

C. SEGMENT 4B LIVER BIOPSY

- Bland fibrosis, old hemorrhage, and dystrophic calcification.
- No evidence of malignancy.

D. PROXIMAL MARGIN OF COMMON BILE DUCT

- Acute and chronic inflammation, fibrosis, and epithelial reactive change.
- No evidence of malignancy

E. PANCREAS, DUODENUM

- Pancreatic adenocarcinoma (see synopsis).
- Chronic pancreatitis with fibrosis and atrophy.
- 10 of 31 lymph nodes are positive for metastasis (10/31).
- Serosal adhesions.

F. DISTAL PANCREATIC MARGIN

- No evidence of malignancy.
- 2 lymph nodes free of metastasis (0/2).

G. LYMPH NODE #3 LEFT

- One lymph node free of metastasis (0/1).

CLF *ICD-6-3*
Adenocarcinoma duct NOS 8500/3
path
Adenocarcinoma NOS 8140/3
Site: Pancreas head C25.0
JS 5/21/14

[page 2 of 6]
Pathology Synoptic

Specimen type: Pancreato-duodenectomy (Whipple procedure)

Tumor location: Head of pancreas, common bile duct with obstruction, peripancreatic soft tissue

Histologic type: Adenocarcinoma (Ductal, per TSS)

Histologic grade: Moderately differentiated

Tumor size: Approximately 3.5 x 2.5 x 2.0 cm

Tumor extent: Tumor extends beyond the pancreas, but without demonstrated involvement of celiac axis or SMA as sampled

Lymphatic invasion: Present

Large vessel invasion: Present

Margins: Common bile duct: Clear

Proximal duodenal or gastric margin: Clear

Distal duodenal margin: Clear

Proximal or distal pancreatic margin: Clear

Peripancreatic soft tissue margin: Positive at SMA surface

Total regional lymph nodes: 33 Number positive: 10

AJCC Pathologic Stage: pT3, pN1 MX

Dictated and authenticated by:

Performing Location:

Gross Description**A. PERITONEAL NODULE**

Received fresh labeled with the patient name

Description: 0.7 cm tan tissue

FROZEN SECTION DIAGNOSIS PERFORMED AT
nodules with fibrous capsules; negative for neoplasm

SECTIONS:

A1. Stained green bisected and all submitted after frozen section

B. RIGHT LIVER NODULE

Received fresh labeled with the patient name

Description: 0.8 cm tan tissue

FROZEN SECTION DIAGNOSIS PERFORMED AT
Crystalloid nodules with fibrous capsules; negative for neoplasm

SECTIONS:

[page 3 of 6]
B1. Stained orange, bisected and all submitted

C. SEGMENT 4B LIVER BIOPSY

Received fresh labeled with the patient name

Description: 1.3 cm dull tissue

FROZEN SECTION DIAGNOSIS PERFORMED AT

Negative for neoplasm

SECTIONS:

C1. Bisected and all submitted after frozen section

D. PROXIMAL MARGIN OF COMMON BILE DUCT

Received fresh labeled with the patient name

Description: Circular portion of gray-white tissue, 1.3 cm in diameter and 0.4 cm in length

FROZEN SECTION DIAGNOSIS PERFORMED AT

Negative for malignancy

SECTIONS:

D1. All submitted after frozen section

E. PANCREAS, DUODENUM

Received fresh labeled with the patient name

Specimen received: Pancreatic head, duodenum and is attached soft tissue

Orientation given: Long suture-SMA margin, short suture-anterior margin

Integrity: Intact

Size of pancreas: 4.9 x 3.9 x 4.5 cm

Length of duodenum: 29.5 cm

Ducts: Common bile duct is obstructed 3.5 cm from the surgical margin and is dilated, duct of Wirsung is patent through the ampulla

Ampulla: No gross lesion

Inking scheme: Anterior-blue, posterior-black, portal vein surface-purple, superior mesenteric artery surface-orange, pancreatic margin and green, common bile duct margin-yellow

Tumor site: Posterior pancreatic head

Tumor size: Approximately 3.5 x 2.5 x 2.0 cm

Tumor description: Poorly defined and sclerotic

Invasion of: Common bile duct

Distance from margins: Less than 0.1 cm from portal vein surface, 0.2 cm from the SMA surface and the posterior margin

Remaining specimen: No other gross abnormality

Lymph nodes: Approximately 20 lymph nodes

SECTIONS:

E1. Proximal duodenal margin

E2. Distal duodenal margin

E3. Pancreatic margin en face

E4. Common bile duct margin

[page 4 of 6]
E5-6. Longitudinal section through the obstructed common bile duct with portal vein surface

E7-10. Sections with portal vein surface

E11-14. SMA surface

E15. Posterior margin

E16. Ampulla

E17. Additional periampullary tissue

E18-20. Three additional sections of posterior pancreatic margin with tumor

E21-22. Two sections with anterior pancreas and lymph nodes

E23. One lymph node, bisected, from anterior pancreas (pyloric)

E24. Four lymph nodes, from anterior pancreas (pyloric)

E25. Three lymph nodes, from anterior pancreas (pyloric)

E26-33. One superior pancreas lymph node all submitted

E34. Three superior pancreas possible lymph nodes

E35. One posterior pancreas lymph node trisected

E36. Five posterior pancreatic lymph nodes

E37. Two distal duodenal lymph nodes

F. DISTAL PANCREATIC MARGIN

Received fresh labeled with the patient name

Description: 3.7 x 1.5 x 1.2 cm portion of apparent pancreas with attached orienting sutures. Prior to sectioning the surgical margin is stained with green dye. Gross tumor is not identified. An attached lymph node is 1.3 cm in greatest dimension

FROZEN SECTION DIAGNOSIS PERFORMED AT

Negative for malignancy

SECTIONS:

F1. Residual tissue submitted after frozen section

F2-3. All of the remaining pancreas

F4. One lymph node serially sectioned and all submitted

G. LYMPH NODE #3 LEFT

Received in formalin labeled with the patient name

Description: 1.3 cm lymph node

SECTIONS:

G1. One lymph node bisected and all submitted

Surg Path Non-Chartable Comment

Diagnosis given directly to surgeon over the telephone/speakerphone A,B

Diagnosis given directly to surgeon in Pathology gross room C

Diagnosis telephoned to Operating Room, read back by circulating nurse F

Edited by:

[page 5 of 6]
Part of case seen in consultation with

(margins, elements of staging)

Per TSS dx discrepancy form,
TCGA tumor is adenocarcinoma, ductal type.

[page 6 of 6]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on _____) Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Pancreatic adenocarcinoma	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Ductal	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	"Ductal" is not mentioned on the pathology report. This case however is ductal adenocarcinoma.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator

Signature

Date

Source: NCI Genomic Data Commons file 08ee5d41-37cb-48f6-8cfe-355320f34f94 (TCGA-XD-AAUI.E5956422-823C-45DD-B365-1E11E53BC495.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).